Somatic mutation profile of tumor specimen TCGA-2G-AALX-01A (aliquot TCGA-2G-AALX-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f945b3a9-ad3e-4f76-9dd5-8878b433a573.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALX-10A (Blood Derived Normal), aliquot TCGA-2G-AALX-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77666ce0-8c52-4a60-b0f7-d3b4102984da

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCR9 | c.754G>A p.A252T (on ENST00000357632 / NM_031200.3; = p.A240T on NM_006641.4) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ECT2L | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FANCI | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXP4 | c.1053G>T p.Q351H (on ENST00000307972 / NM_001012426.1; = p.Q350H on NM_138457.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- IKZF3 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- RGS4 | c.378G>A p.E126= | Splice Region (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- TRAF3 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- HRC | c.615C>T p.A205= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, varscan2
- SPATA25 | c.504C>A p.P168= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
